Surgical pathology report (de-identified scan), TCGA case TCGA-WL-A834, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Kansas, specimen TCGA-WL-A834-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

NAME:		SURG PATH #:	
MR #:		SPECIMEN CLASS:	
BILLING #:		ALT ID #:	
LOCATION:		DATE OF PROCEDURE:	
AGE:	SEX: F	DATE RECEIVED:	
DOB:		TIME RECEIVED:	
PHYSICIAN:		DATE OF REPORT:	
COPY TO:		DATE OF PRINTING:	

Material Received:

- A: uterus, cervix, bilateral tubes and ovaries
- B: left pelvic and common lymph nodes
- C: right pelvic and common lymph nodes

History:

year-old female with a history of squamous cell carcinoma of the cervix.

Final Diagnosis:

- A. Uterus, cervix, bilateral tubes and ovaries, hysterectomy and bilateral salpingo-oophorectomy:
Invasive squamous cell carcinoma, 2.9 cm, poorly differentiated; see comment.
- B. Lymph nodes, "left pelvic and common," dissection:
Metastatic squamous cell carcinoma in two of fifteen lymph nodes (2/15).
- C. Lymph nodes, "right pelvic and common," dissection:
Metastatic squamous cell carcinoma in one of thirteen lymph nodes (2/13).

Comment:

UTERINE CERVIX:

Specimen: Uterus with cervix and bilateral tubes and ovaries
Procedure: Hysterectomy and bilateral salpingo-oophorectomy:
Tumor Size: 2.9 cm
Tumor Site:

Cervix

Histologic Type:

Squamous cell carcinoma
G3: Poorly differentiated

Stromal Invasion: Present

Maximum Depth of Invasion: 13 mm

Wall Thickness at Area of Maximum Invasion: 19 mm

Horizontal extent: 25 mm

Margins: Free of tumor

Endocervix:

Involved by invasive carcinoma

ICD O-3
Carcinoma, squamous cell NOS
8070/3

Site: Cervix NOS
C53.9

9/11/14

MR #:

Page 1 of 3

Date of Printing:

SURGICAL PATHOLOGY REPORT

Order Number:

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

Exocervical Margin

Not involved by invasive carcinoma
Distance of invasive carcinoma from margin: 4 mm

Deep Margin

Not involved by invasive carcinoma

Lymph-Vascular Invasion: Present

Lymph Nodes:

Number Examined: 28
Number Involved: 4

Pathologic Staging (pTNM): pT1a1N1M n/a

TNM Descriptors (required only if applicable) (select all that apply)

m (multiple primary tumors)

r (recurrent)

y (post-treatment)

Primary Tumor (pT)

pT1: Cervical carcinoma confined to uterus (extension to corpus should be disregarded)

pT1a: Invasive carcinoma diagnosed by microscopy only. All macroscopically visible lesions (even with superficial invasion) are pT1b/1B.

pT1a1: Stromal invasion ≤ 3.0 mm in depth and horizontal spread ≤ 7.0 mm

pT1a2: Stromal invasion > 3.0 mm but not more than 5.0 mm in depth and horizontal spread ≤ 7.0 mm

pT1b: Clinically visible lesion confined to the cervix or microscopic lesion greater than T1a2/1A2

pT1b1: Clinically visible lesion ≤ 4.0 cm in greatest dimension

pT1b2: Clinically visible lesion > 4.0 cm in greatest dimension

Regional Lymph Nodes (pN)

pN1: Regional lymph node metastasis

Distant Metastasis (pM)

Not applicable

The pathologic stage assigned here should be regarded as provisional, as it reflects only current pathologic data and does not incorporate full knowledge of the patient's clinical status and/or prior pathology.

Attestation:

By this signature, I attest that I have personally formulated the final interpretation expressed in this report and that the above diagnosis is based upon my examination of the slides and/or other material indicated in this report.

Interpreted by:

Electronically Signed Out By

Attending Physician

M.D. Resident

Gross Description:

A. Received fresh labeled with the patient's name and "uterus, cervix, bilateral tubes and ovaries" and consists of a 121 gram radical hysterectomy specimen with included bilateral tubes and ovaries measuring 8.5 cm from uterine fundus to cervical os, 4.7 cm from cornu to cornu, and 4.0 cm from anterior to posterior. The serosa is pink-tan and smooth without gross evidence of lesion. The vaginal cuff is measured prior to formalin fixation and measures 0.8 cm at the 12:00 position, 2.2 cm at the 6:00 position, 1.0 cm at the 3:00 position and 0.9 cm at the 9:00 position. The cervical os is slit like and measures 1.0 cm. There is a 2.5 x 2.4 x 2.9 cm white-tan ill-defined rubbery mass located at the cervical os and lower uterine segment of the anterior and posterior uterus and appears to efface the cervix. The mass extends 2.0 cm beyond the cervical os. The right perimetrium measures 3.0 x 1.9 x 1.3 cm, the left perimetrium measures 2.8 x 2.2 x 1.1 cm. The posterior resection margin is inked black, the anterior resection margin is inked blue, and the circumferential vaginal cuff resection margin is inked green. The cervical os is probed patent, and the uterus is bisected coronally to reveal a 2.5 x 1.2 x 0.4 cm endometrial cavity and a 3.0 x 0.6 cm endocervical canal. The mass invades to a depth of 1.1 cm and is 0.2 cm from the outer surface. The mass extends into the endocervical canal and is 0.8 cm from the vaginal cuff margin. The uterus is serially sectioned to reveal an average endometrial

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

thickness of 0.2 cm. There are two ovaries with fallopian tubes included in the specimen which have been removed prior to receipt.

Fallopian tube #1 measures 5.5 x 0.4 cm. The fallopian tube is serially sectioned to reveal a pinpoint lumen. Adjacent to the fallopian tube is the ovary, measuring 2.2 x 1.0 x 1.3 cm. The ovary is serially sectioned to reveal multiple corpora albicantia and no gross abnormalities are seen.

The other fallopian tube #2 measures 4.5 x 0.4 cm. It is serially sectioned to reveal pinpoint lumen. Adjacent to the fallopian tube is the ovary, measuring 1.8 x 1.4 x 0.7 cm. The ovary is serially sectioned to reveal no gross abnormalities. The serosa is tan-brown and smooth. Sections are submitted as follows:

- A1 12:00 Cervix with vaginal cuff.
- A2 6:00 Cervix with vaginal cuff.
- A3 3:00 Cervix with vaginal cuff.
- A4 9:00 Cervix with vaginal cuff.
- A5 1:00 Cervix with vaginal cuff.
- A6 10:00 Cervix with vaginal cuff.
- A7 4:00 Cervix with vaginal cuff.
- A8 7:00 Cervix with vaginal cuff.
- A9 Right perimetrium.
- A10 Left perimetrium.
- A11 Anterior lower uterine segment.
- A12 Posterior lower uterine segment.
- A13 Anterior full thickness wall.
- A14 Full thickness posterior wall.
- A15 Representative sections of fallopian tube #1.
- A16 Representative section of the ovary #1.
- A17 Representative sections of fallopian tube #2.
- A18 Representative sections of ovary #2.

B. Received in formalin labeled with the patient's name and "left pelvic and common lymph nodes" is a 6.5 x 4.5 x 1.5 cm aggregate of yellow-pink adipose tissue. The specimen is palpated to reveal fifteen possible lymph nodes ranging in size from 0.3 x 0.3 x 0.3 cm up to 2.0 x 1.0 x 0.4 cm. The specimen is submitted as follows:

- B1 Three possible lymph nodes.
- B2 Six possible lymph nodes.
- B3 Two possible lymph nodes.
- B4 Two possible lymph nodes (one inked black and bisected).
- B5 One possible lymph node.

C. Received in formalin labeled with the patient's name and "right pelvic and common lymph nodes" is a 7.5 x 7.0 x 2.0 cm aggregate of yellow-red adipose tissue. The specimen is palpated to reveal fourteen possible lymph nodes ranging in size from 0.2 x 0.1 x 0.1 cm up to 2.3 x 1.5 x 0.5 cm. The specimen is submitted as follows:

- C1 Six possible lymph nodes.
- C2 Four possible lymph nodes.
- C3 One possible lymph node, bisected.
- C4 Two possible lymph nodes.
- C5 One possible lymph node, bisected.

M.D. Resident

If immunohistochemical stains and/or in situ hybridization are cited in this report, the performance characteristics were determined by the regulations. Some of these tests rely on the use of "analyte specific reagents" and are subject to specific labeling requirements by the FDA. Known positive and negative control tissues demonstrate appropriate staining. This testing was developed by the [redacted] in compliance with CLIA'88. It has not been cleared or approved by the FDA. The FDA has determined that such clearance or approval is not necessary.

Date of Printing:

MR #:

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file 246b885f-ab94-46e8-8728-3b9bc114abb9 (TCGA-WL-A834.BADCCC27-5838-469E-97AC-FADBE3757376.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).